FM case AD10885 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Skin.
https://portal.gdc.cancer.gov/cases/92c66139-ba88-4d19-b84e-8c48df2554b0

Male, 73.0 years: Squamous cell carcinoma, NOS (ICD-O-3 8070/3) of the skin; metastasis biopsied or resected from the lymph node. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Metastatic.
